Gene-level copy-number profile of tumor specimen TCGA-HD-7753-01A from TCGA case TCGA-HD-7753, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.4 years (22,774 days).
Specimen TCGA-HD-7753-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.b06f2c86-b9a7-494e-bbd1-ffc71105e235.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HD-7753-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/50b91871-4f21-4aff-b332-6e12783a760f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 929; copy number 2: 19,318; copy number 3: 13,418; copy number 4: 23,659; copy number 5: 716; copy number 6: 1,369; copy number 7: 178; copy number 8: 11; copy number 9: 102; copy number 11: 57; copy number 15: 9; copy number 16: 21; copy number 18: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HD-7753-01A-11D-2077-01): tumor purity 0.63, ploidy 1.66, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,128,103, 7 genes (within-gene range 0–2): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 213 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:99,500,347–101,320,575, 26 genes, copy number 9–16 (within-gene range 6–16): AC078828.1, AC107029.1, AC107029.2, COL8A1, AC069222.1, CMSS1, FILIP1L, MIR3921, AC129803.1, TMEM30CP, DUSP12P1, VTI1BP1, TBC1D23, NIT2, TOMM70, LNP1, TMEM45A, ADGRG7, AC069223.1, GMFBP1, TFG, ABI3BP, AC080014.1, RNU6-865P, ACTR3P3, IMPG2.
- chr3:101,521,891–102,479,841, 23 genes, copy number 9 (within-gene range 2–9): FAM172BP, TRMT10C, PCNP, AC073861.1, AC084198.1, RNU6-1256P, Y_RNA, Y_RNA, ZBTB11, RNY1P12, ZBTB11-AS1, RPL24, AC084198.2, PDCL3P4, CEP97, NXPE3, AC020651.1, NFKBIZ, AC020651.2, LINC02085, Y_RNA, AC106712.1, ZPLD1.
- chr8:37,908,738–38,382,272, 24 genes, copy number 9: RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1.
- chr11:68,612,899–71,252,577, 65 genes, copy number 11–18 (within-gene range 4–18) (broad region; genes not listed).
- chr11:102,047,437–102,727,050, 22 genes, copy number 11: CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8.
- chr11:102,751,070–102,780,628, 3 genes, copy number 11: AP000619.1, AP000619.3, MMP10.
- chr18:47,808,957–49,851,059, 50 genes, copy number 9 (within-gene range 7–9): SMAD2, MTCO2P2, AC120349.3, AC120349.1, AC120349.2, ZBTB7C, AC105101.1, AC105101.2, RNU6-708P, C18orf12, RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1, AC100778.1, AC100778.4, PRR13P4, C18orf32, RPL17-C18orf32, AC100778.2, AC100778.3, MIR1539, RPL17, SNORD58C, SNORD58A, SNORD58B, SRP72P1, LINC02837, LIPG, SMUG1P1, AC090227.3, ACAA2, AC090227.2, SNHG22, SCARNA17, AC090227.1.

Autosomal genes at a single copy (total copy number 1): 929. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
